Somatic mutation profile of tumor specimen ALCH-B29I-TTP1-A (aliquot ALCH-B29I-TTP1-A-1-0-D-A775-36) from ALCHEMIST case ALCH-B29I, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 84.8 years (30,960 days).
Specimen ALCH-B29I-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61ccf4aa-85bf-4939-b522-8738168e6af8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B29I-NB1-A (Blood Derived Normal), aliquot ALCH-B29I-NB1-A-1-0-D-A775-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a019771-036b-478d-9a68-46e2ff67c0dd

The open-access MAF lists 155 somatic variants for this specimen: 99 protein-altering or splice-affecting, 36 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 36, Intron 13, Frame Shift Del 6, Nonsense Mutation 5, 5'UTR 4, Splice Region 3, Splice Site 2, RNA 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB2 | c.2372C>T p.T791M | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.434); catalogued as rs774818699, COSV57070793; called by muse, mutect2
- ALK | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs748978993, COSV66568642, COSV66579450; called by muse, mutect2, varscan2
- ANO4 | c.2818C>T p.R940* (on ENST00000392977 / NM_001286615.2; = p.R905* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 6/100 reads (6%) | catalogued as rs763133235; called by muse, mutect2
- APC | c.1061C>G p.P354R | Missense Mutation (SNP) | VAF 75/313 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57330991, COSV57365091; called by muse, mutect2, varscan2
- BRWD3 | c.1450G>T p.A484S | Missense Mutation (SNP) | VAF 11/262 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV64746116; called by muse, mutect2
- CDKL5 | c.1061C>A p.P354H | Missense Mutation (SNP) | VAF 51/362 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.417); catalogued as COSV66110550; called by muse, mutect2, varscan2
- CIT | c.1621G>C p.D541H | Missense Mutation (SNP) | VAF 11/213 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55866348; called by muse, mutect2
- CSTF1 | c.878C>T p.S293L | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53858641; called by muse, mutect2
- CYP11B1 | c.1066C>A p.Q356K | Missense Mutation (SNP) | VAF 19/344 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.645); catalogued as CM930177; called by muse, mutect2
- DMD | c.8999G>A p.R3000H | Missense Mutation (SNP) | VAF 66/412 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs772695216, COSV58901389, COSV58903962; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSG3 | c.1478C>A p.P493Q | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57128606; called by muse, mutect2
- ECPAS | c.1780C>T p.R594C | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761135409; called by muse, mutect2, varscan2
- EZHIP | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.081); catalogued as rs1334894799; called by muse, mutect2
- FBXL16 | c.1086G>A p.M362I | Missense Mutation (SNP) | VAF 32/224 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as COSV60963870; called by muse, mutect2, varscan2
- FER1L5 | c.6151G>A p.A2051T (on ENST00000623019; = p.A2015T on NM_001293083.2) | Missense Mutation (SNP) | VAF 19/372 reads (5%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as rs1333621476; called by muse, mutect2
- GNAL | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 107/360 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.031); catalogued as COSV52329015, COSV52334061; called by muse, mutect2, varscan2
- GNL3 | c.491C>A p.A164D | Missense Mutation (SNP) | VAF 32/228 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV101187280; called by muse, mutect2, varscan2
- GRM8 | c.1402C>T p.P468S | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.18); catalogued as rs1255376883, COSV58817431; called by muse, mutect2
- H1-2 | c.217G>A p.V73M | Missense Mutation (SNP) | VAF 49/382 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773914281; called by muse, mutect2, varscan2
- HECTD4 | c.10522G>C p.D3508H | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); catalogued as COSV101107259; called by muse, mutect2
- KIF26A | c.3367G>A p.D1123N | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1185701827, COSV59471322; called by muse, mutect2
- KLC3 | c.1380-1G>A p.X460_splice | Splice Site (SNP) | VAF 8/130 reads (6%) | catalogued as rs1372452347; called by muse, mutect2
- LORICRIN | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 10/124 reads (8%) | PolyPhen probably damaging (0.977); catalogued as rs1557795654; called by muse, mutect2
- LRP1B | c.13101del p.H4368Tfs*4 | Frame Shift Del (DEL) | VAF 37/236 reads (16%) | catalogued as rs751694974; called by mutect2, pindel, varscan2
- MTTP | c.2314C>A p.R772S | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55506757; called by muse, mutect2, varscan2
- MYO7B | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 9/271 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.141); catalogued as rs866178227, COSV67347469; called by muse, mutect2
- NAGS | c.1494G>C p.W498C | Missense Mutation (SNP) | VAF 39/416 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM167136; called by muse, mutect2
- OSBPL5 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs752828587, COSV55142252; called by muse, mutect2, varscan2
- RBM10 | c.460G>A p.V154M | Missense Mutation (SNP) | VAF 85/494 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.786); catalogued as rs369088033; called by muse, mutect2, varscan2
- SCLT1 | c.810G>T p.E270D | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99828487; called by muse, mutect2, varscan2
- TFE3 | c.888G>A p.L296= | Splice Region (SNP) | VAF 25/153 reads (16%) | catalogued as COSV59947964; called by muse, mutect2, varscan2
- VCAN | c.8480C>A p.S2827Y | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as rs955434648; called by muse, mutect2
- VPS13D | c.11281G>C p.E3761Q | Missense Mutation (SNP) | VAF 18/201 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as COSV50636618; called by muse, mutect2
- WDFY4 | c.1994C>T p.P665L | Missense Mutation (SNP) | VAF 56/281 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as rs1329207041, COSV57450020; called by muse, mutect2, varscan2
- WFIKKN2 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.472); catalogued as rs753365907; called by muse, mutect2
- ADAMTS18 | c.3214G>T p.V1072L | Missense Mutation (SNP) | VAF 85/390 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADRA2B | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 20/400 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- AKAP6 | c.5174C>T p.S1725L | Missense Mutation (SNP) | VAF 28/309 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- AVPR2 | c.560G>A p.S187N | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.405); called by muse, mutect2
- BRINP1 | c.2042C>A p.T681K | Missense Mutation (SNP) | VAF 56/225 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- C3orf38 | c.468G>C p.Q156H | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.269); called by muse, mutect2
- CCT7 | c.679A>G p.M227V | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- CELSR3 | c.1273G>A p.D425N | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CFAP46 | c.3907C>A p.R1303S | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- CNGB3 | c.1200G>T p.W400C | Missense Mutation (SNP) | VAF 10/215 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- CTBP2 | c.368T>A p.V123E | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- DCAF8L2 | c.926A>T p.N309I | Missense Mutation (SNP) | VAF 55/345 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- DCHS2 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 15/259 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DMD | c.6465del p.Q2156Kfs*7 | Frame Shift Del (DEL) | VAF 29/286 reads (10%) | called by mutect2, pindel, varscan2
- DNAI3 | c.2410-1G>A p.X804_splice | Splice Site (SNP) | VAF 5/63 reads (8%) | called by muse, mutect2
- E2F3 | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2
- ECEL1 | c.529C>A p.Q177K | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ESPL1 | c.4099G>T p.E1367* | Nonsense Mutation (SNP) | VAF 7/132 reads (5%) | called by muse, mutect2
- FANCD2 | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); called by muse, mutect2
- FLT3 | c.341G>T p.C114F | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- GORAB | c.635A>T p.Q212L | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.943); called by muse, mutect2
- GPATCH2L | c.581T>G p.L194R | Missense Mutation (SNP) | VAF 55/250 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- GSX2 | c.413A>C p.H138P | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- HPGDS | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.414); called by muse, mutect2
- HS6ST2 | c.319C>A p.L107M | Missense Mutation (SNP) | VAF 9/209 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- ICE1 | c.2134G>C p.A712P | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- IGKV5-2 | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 22/371 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- KANSL2 | c.643C>T p.Q215* | Nonsense Mutation (SNP) | VAF 18/97 reads (19%) | called by muse, mutect2, varscan2
- KCND1 | c.1094A>G p.Y365C | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- KIF7 | c.3209T>A p.L1070H | Missense Mutation (SNP) | VAF 33/396 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LAMA5 | c.8353A>G p.M2785V | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- LEFTY1 | c.224del p.G75Efs*71 | Frame Shift Del (DEL) | VAF 31/203 reads (15%) | called by mutect2, pindel, varscan2
- LRRIQ1 | c.4078A>T p.R1360W | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2
- LRRTM1 | c.965T>G p.V322G | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2
- MACF1 | c.18352A>T p.T6118S (on ENST00000372915; = p.T4163S on NM_012090.5) | Missense Mutation (SNP) | VAF 21/110 reads (19%) | called by muse, mutect2, varscan2
- METTL17 | c.1304A>G p.D435G | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MRTO4 | c.532G>T p.E178* | Nonsense Mutation (SNP) | VAF 34/412 reads (8%) | called by muse, mutect2
- NHS | c.2815T>C p.Y939H | Missense Mutation (SNP) | VAF 20/522 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR2W1 | c.776A>G p.Y259C | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- OR4Q3 | c.136A>G p.I46V | Missense Mutation (SNP) | VAF 36/356 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2
- OR6K2 | c.76G>T p.V26F | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDH18 | c.3065C>A p.T1022N | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDE3B | c.784G>T p.G262W | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- POLA2 | c.1278G>C p.L426F | Missense Mutation (SNP) | VAF 26/375 reads (7%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.819); called by muse, mutect2
- POTEI | c.334A>G p.S112G | Missense Mutation (SNP) | VAF 41/338 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- PRPF31 | c.1210A>C p.S404R | Missense Mutation (SNP) | VAF 37/342 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- PRPF40B | c.1610-3C>A | Splice Region (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2, varscan2
- RHOD | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- RHOT1 | c.1333-3C>T | Splice Region (SNP) | VAF 14/162 reads (9%) | called by muse, mutect2
- RPS4X | c.159G>T p.K53N | Missense Mutation (SNP) | VAF 10/282 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.469); called by muse, mutect2
- SEMA3E | c.2274G>C p.K758N | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2
- SLC27A4 | c.1595_1620del p.A532Gfs*21 | Frame Shift Del (DEL) | VAF 60/290 reads (21%) | called by mutect2, pindel
- SPATA16 | c.487G>T p.V163L | Missense Mutation (SNP) | VAF 20/368 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2
- STAB2 | c.5474_5482delinsC p.D1825Afs*25 | Frame Shift Del (DEL) | VAF 27/140 reads (19%) | called by pindel, varscan2*
- TKTL2 | c.564G>T p.L188F | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2
- TP53 | c.467_483del p.R156Hfs*19 | Frame Shift Del (DEL) | VAF 45/161 reads (28%) | called by mutect2, pindel, varscan2
- TTN | c.94226A>C p.K31409T (on ENST00000591111; = p.K23985T on NM_003319.4) | Missense Mutation (SNP) | VAF 16/218 reads (7%) | PolyPhen probably damaging (0.964); called by muse, mutect2
- UGT2A3 | c.1202T>A p.I401K | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- VAV2 | c.652G>T p.E218* (on ENST00000371850 / NM_001134398.2; = p.E213* on NM_003371.4) | Nonsense Mutation (SNP) | VAF 23/95 reads (24%) | called by muse, mutect2, varscan2
- VSIG4 | c.1046C>A p.T349N | Missense Mutation (SNP) | VAF 24/388 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2
- YLPM1 | c.4896G>C p.K1632N | Missense Mutation (SNP) | VAF 33/271 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ZCWPW2 | c.740T>C p.F247S | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2
- ZFHX4 | c.5471A>T p.Q1824L | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- ZNF474 | c.515G>T p.G172V | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BBS9 | c.816G>A p.K272= | Silent (SNP) | VAF 55/219 reads (25%) | called by muse, mutect2, varscan2
- CASP4 | c.318C>T p.L106= | Silent (SNP) | VAF 7/128 reads (5%) | called by muse, mutect2
- CDKL5 | c.1062C>A p.P354= | Silent (SNP) | VAF 54/370 reads (15%) | called by muse, mutect2, varscan2
- CEACAM18 | c.819C>A p.L273= | Silent (SNP) | VAF 14/362 reads (4%) | called by muse, mutect2
- CRACD | c.2664C>T p.S888= | Silent (SNP) | VAF 7/98 reads (7%) | catalogued as rs1345587979; called by muse, mutect2
- DCST2 | c.2067C>G p.L689= | Silent (SNP) | VAF 24/140 reads (17%) | called by muse, mutect2, varscan2
- DMD | c.8844C>T p.L2948= | Silent (SNP) | VAF 16/331 reads (5%) | called by muse, mutect2
- DPYD | c.2095A>C p.R699= | Silent (SNP) | VAF 34/430 reads (8%) | called by muse, mutect2
- EIF3F | c.384A>T p.S128= | Silent (SNP) | VAF 40/216 reads (19%) | called by muse, mutect2, varscan2
- FAM170B | c.408C>A p.P136= | Silent (SNP) | VAF 49/248 reads (20%) | called by muse, mutect2, varscan2
- FSCB | c.129C>T p.A43= | Silent (SNP) | VAF 14/51 reads (27%) | called by muse, mutect2, varscan2
- GRAMD1A | c.1824G>A p.L608= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as rs1321315026; called by muse, mutect2, varscan2
- HTR1B | c.456G>A p.T152= | Silent (SNP) | VAF 17/395 reads (4%) | called by muse, mutect2
- IRX6 | c.939G>A p.A313= | Silent (SNP) | VAF 44/201 reads (22%) | called by muse, mutect2, varscan2
- KBTBD11 | c.1242C>G p.L414= | Silent (SNP) | VAF 41/241 reads (17%) | called by muse, mutect2, varscan2
- KCNK10 | c.1392C>A p.T464= | Silent (SNP) | VAF 112/544 reads (21%) | catalogued as COSV100068098; called by muse, mutect2, varscan2
- KDM2A | c.1149A>T p.R383= | Silent (SNP) | VAF 26/132 reads (20%) | catalogued as rs368375687; called by muse, mutect2, varscan2
- MAP3K15 | c.3357C>T p.I1119= | Silent (SNP) | VAF 5/83 reads (6%) | called by muse, mutect2
- MOSPD2 | c.204T>C p.S68= | Silent (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2
- MUC17 | c.7398G>A p.T2466= | Silent (SNP) | VAF 13/185 reads (7%) | catalogued as rs752258367; called by muse, mutect2
- NID1 | c.3300G>A p.R1100= | Silent (SNP) | VAF 22/334 reads (7%) | called by muse, mutect2
- NLRP3 | c.1660C>A p.R554= | Silent (SNP) | VAF 105/537 reads (20%) | catalogued as CM060237; called by muse, mutect2, varscan2
- NPHS1 | c.495G>A p.A165= | Silent (SNP) | VAF 20/296 reads (7%) | catalogued as rs533934522, COSV62287047; called by muse, mutect2
- POC1A | c.804C>T p.H268= | Silent (SNP) | VAF 19/141 reads (13%) | catalogued as rs201155173; called by muse, mutect2, varscan2
- RBM17 | c.129A>G p.Q43= | Silent (SNP) | VAF 34/160 reads (21%) | called by muse, mutect2
- RPL10L | c.270G>T p.R90= | Silent (SNP) | VAF 46/241 reads (19%) | called by muse, mutect2, varscan2
- RRAGA | c.417G>C p.L139= | Silent (SNP) | VAF 22/322 reads (7%) | catalogued as rs1376223840; called by muse, mutect2
- RYR1 | c.4860C>T p.G1620= | Silent (SNP) | VAF 17/248 reads (7%) | catalogued as rs200979691, COSV100614712; called by muse, mutect2
- SCN5A | c.4128C>G p.T1376= (on ENST00000333535 / NM_198056.3; = p.T1375= on NM_000335.5) | Silent (SNP) | VAF 14/318 reads (4%) | catalogued as rs1329178767; called by muse, mutect2
- SLC25A42 | c.429G>A p.T143= | Silent (SNP) | VAF 16/250 reads (6%) | called by muse, mutect2
- SLC27A4 | c.1401C>T p.G467= | Silent (SNP) | VAF 10/149 reads (7%) | called by muse, mutect2
- SRPK2 | c.285C>T p.V95= | Silent (SNP) | VAF 16/226 reads (7%) | catalogued as rs761945620; called by muse, mutect2
- TMEM132C | c.1866C>T p.H622= | Silent (SNP) | VAF 22/161 reads (14%) | catalogued as rs190794438; called by muse, mutect2, varscan2
- TMPRSS11A | c.1257A>G p.T419= | Silent (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2
- TRADD | c.99G>C p.A33= | Silent (SNP) | VAF 64/387 reads (17%) | catalogued as COSV50757747, COSV50758005; called by muse, mutect2, varscan2
- WDR97 | c.4467C>T p.F1489= | Silent (SNP) | VAF 12/164 reads (7%) | called by muse, mutect2
- ATP2B3 | c.3342+4640C>T | Intron (SNP) | VAF 36/160 reads (23%) | called by muse, mutect2, varscan2
- C6orf201 | c.285-6337C>A | Intron (SNP) | VAF 12/104 reads (12%) | called by muse, mutect2
- CHCHD3 | c.170-11321G>A | Intron (SNP) | VAF 12/144 reads (8%) | called by muse, mutect2
- DDR2 | c.1728+35G>A | Intron (SNP) | VAF 10/224 reads (4%) | called by muse, mutect2
- ELP1 | c.3573-36C>T | Intron (SNP) | VAF 11/94 reads (12%) | called by muse, mutect2, varscan2
- ENPEP | c.1510-900C>T | Intron (SNP) | VAF 15/140 reads (11%) | called by muse, mutect2, varscan2
- FSD1 | c.490+13C>T | Intron (SNP) | VAF 11/80 reads (14%) | catalogued as rs377103581; called by muse, mutect2, varscan2
- HSPA12A | c.-19G>A | 5'UTR (SNP) | VAF 12/104 reads (12%) | called by muse, mutect2, varscan2
- IMPG1 | c.2045-3898G>C | Intron (SNP) | VAF 8/71 reads (11%) | called by muse, mutect2
- KLHL14 | c.-44+525C>T | Intron (SNP) | VAF 16/61 reads (26%) | catalogued as rs1424935225; called by muse, mutect2, varscan2
- LMO2 | c.-190G>A | 5'UTR (SNP) | VAF 15/127 reads (12%) | called by muse, mutect2, varscan2
- LRR1 | chr14:49598690 C>T | 5'Flank (SNP) | VAF 19/416 reads (5%) | catalogued as rs1378766880; called by muse, mutect2
- MARCHF1 | c.242+643C>G | Intron (SNP) | VAF 13/170 reads (8%) | catalogued as rs1216388108; called by muse, mutect2
- NME3 | c.47-33C>T | Intron (SNP) | VAF 5/51 reads (10%) | catalogued as rs1281873568; called by muse, mutect2
- PDE7B | c.711+89C>A | Intron (SNP) | VAF 45/271 reads (17%) | called by muse, mutect2, varscan2
- PLRG1 | c.-24G>T | 5'UTR (SNP) | VAF 17/182 reads (9%) | catalogued as COSV100123295; called by muse, mutect2, varscan2
- RANBP1 | c.505+116G>A | Intron (SNP) | VAF 16/342 reads (5%) | catalogued as rs570432689; called by muse, mutect2
- REXO1L1P | chr8:85655078 C>A | 3'Flank (SNP) | VAF 24/1532 reads (2%) | called by muse, mutect2
- SYPL2 | c.-7C>T | 5'UTR (SNP) | VAF 10/224 reads (4%) | called by muse, mutect2
- TAAR3P | n.755A>G | RNA (SNP) | VAF 8/213 reads (4%) | called by muse, mutect2
